Somatic mutation profile of tumor specimen 0DSBYI from CCDI case PBCHZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ossifying fibromyxoid tumor; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.0 years (4,029 days).
Specimen 0DSBYI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f9fc179-9b3c-4b00-8570-138715129bf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSBY9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7a2f62a-e804-40c1-9a1c-6ddb1edb703a

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 4, Frame Shift Del 3, 5'UTR 2, 3'UTR 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC139530.2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767180827, COSV99075686; called by muse, mutect2, varscan2
- ARHGAP40 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 154/399 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV54810042; called by muse, mutect2, varscan2
- CACNA1C | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 111/653 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as rs775414849, COSV59721389; called by muse, mutect2, varscan2
- ICE1 | c.2678G>A p.G893D | Missense Mutation (SNP) | VAF 198/441 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1358737524; called by muse, mutect2, varscan2
- RNF151 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369087548; called by muse, mutect2, varscan2
- SELE | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 144/365 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs754829637; called by muse, mutect2, varscan2
- SLC1A6 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 334/1269 reads (26%) | catalogued as rs1298757213, COSV55674969; called by muse, mutect2, varscan2
- USP47 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV60466015; called by muse, mutect2
- VSIG10L | c.1123C>G p.R375G | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs756431754; called by muse, mutect2, varscan2
- C16orf96 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2
- COL1A2 | c.2769A>T p.E923D | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- DCAF4L1 | c.727T>A p.C243S | Missense Mutation (SNP) | VAF 37/511 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2
- DDX3X | c.1985G>C p.*662Sext*27 (on ENST00000399959; = p.*663Sext*27 on NM_001356.5) | Nonstop Mutation (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- FAM78B | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GABBR1 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GFM2 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.062); called by muse, mutect2
- GLB1L2 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- HDLBP | c.1225_1226del p.T409Pfs*24 | Frame Shift Del (DEL) | VAF 106/444 reads (24%) | called by mutect2, varscan2
- KCNQ2 | c.1271C>G p.P424R | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- KCNU1 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 125/318 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRP2 | c.9567G>T p.K3189N | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- MEF2C | c.643_668del p.G215Rfs*8 | Frame Shift Del (DEL) | VAF 56/282 reads (20%) | called by mutect2, varscan2
- MUC16 | c.25307T>G p.V8436G | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2
- OR11H6 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGAM5 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- PHOX2A | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- SPTA1 | c.1946A>T p.E649V | Missense Mutation (SNP) | VAF 52/469 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- TECPR1 | c.2697_2700del p.Y899* | Frame Shift Del (DEL) | VAF 132/348 reads (38%) | called by mutect2, varscan2
- ARHGAP35 | c.3471G>A p.L1157= | Silent (SNP) | VAF 108/166 reads (65%) | catalogued as rs758176207; called by muse, mutect2, varscan2
- FYB2 | c.534T>G p.T178= | Silent (SNP) | VAF 30/624 reads (5%) | called by muse, mutect2
- OR7C2 | c.483G>A p.L161= | Silent (SNP) | VAF 216/743 reads (29%) | called by muse, mutect2, varscan2
- SIRPG | c.441T>G p.S147= | Silent (SNP) | VAF 54/562 reads (10%) | called by muse, mutect2
- ZNF727 | c.714C>A p.T238= | Silent (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- ATP5F1C | c.91+82T>A | Intron (SNP) | VAF 46/56 reads (82%) | called by muse, mutect2, varscan2
- ITGB6 | c.-96T>C | 5'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- MYO9B | c.5624+70C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- POU5F1 | c.-16G>A | 5'UTR (SNP) | VAF 8/106 reads (8%) | catalogued as rs1304895062; called by muse, mutect2
- SH3GL3 | c.839-6662C>T | Intron (SNP) | VAF 107/231 reads (46%) | called by muse, mutect2, varscan2
- TRABD2B | c.*64G>C | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- VIRMA | c.4383+100T>C | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
